Somatic mutation profile of tumor specimen C3N-00646-04 (aliquot CPT0082000009) from CPTAC case C3N-00646, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.9 years (21,144 days).
Specimen C3N-00646-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47cc51c6-cb2b-474e-af36-d086f3820437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00646-71 (Blood Derived Normal), aliquot CPT0082030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/879ba10f-6501-4591-a5b3-2e004b3016e3

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 11 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 11, Frame Shift Del 6, Nonsense Mutation 6, 3'UTR 3, Splice Region 3, 3'Flank 3, Intron 3, 5'UTR 2, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHEB | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 39/240 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519950, COSV51262364, COSV51263550; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs796051897; called by muse, mutect2
- ACTL7B | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480803021; called by muse, mutect2, varscan2
- ATAD2 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.098); catalogued as COSV54881193; called by muse, mutect2, varscan2
- DDX50 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104424183; called by muse, mutect2, varscan2
- EFR3A | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1359496595; called by muse, mutect2, varscan2
- ELAVL4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1345370346, COSV63914597; called by muse, mutect2
- GRIN3A | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62453111; called by muse, mutect2, varscan2
- HS3ST2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 51/235 reads (22%) | catalogued as rs1336994762, COSV54457839; called by muse, mutect2, varscan2
- PAM | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57216591; called by muse, mutect2, varscan2
- PASD1 | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1306096843; called by muse, mutect2, varscan2
- RFX6 | c.1715C>A p.S572* | Nonsense Mutation (SNP) | VAF 57/358 reads (16%) | catalogued as COSV60585069; called by muse, mutect2, varscan2
- SLC38A1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV67064301; called by muse, mutect2, varscan2
- TFE3 | c.114C>A p.L38= | Splice Region (SNP) | VAF 29/138 reads (21%) | catalogued as COSV59946412; called by muse, mutect2, varscan2
- TFIP11 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV53226609; called by muse, mutect2
- USP38 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761444526; called by muse, mutect2
- VANGL2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759727082; called by muse, mutect2
- ZP3 | c.1183G>T p.A395S (on ENST00000394857 / NM_001110354.2; = p.A344S on NM_007155.6) | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as COSV100334553; called by muse, mutect2, varscan2
- ABCA1 | c.5935T>G p.S1979A | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- C12orf40 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CALB2 | c.628-2A>T p.X210_splice | Splice Site (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- CCDC57 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CDCA2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CLMN | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CSTF2T | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- ENPEP | c.1021T>G p.Y341D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EVI5 | c.1549A>G p.R517G | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FARP2 | c.1255_1259delinsTG p.L419_P420delins* | Nonsense Mutation (DEL) | VAF 47/253 reads (19%) | called by pindel, varscan2*
- FBRS | c.722del p.P241Lfs*63 (on ENST00000287468; = p.P761Lfs*63 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 32/185 reads (17%) | called by mutect2, pindel, varscan2
- GGA3 | c.801del p.S267Rfs*43 (on ENST00000537686 / NM_138619.4; = p.S234Rfs*43 on NM_014001.5) | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.9581T>C p.I3194T | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GULP1 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIAA0100 | c.2530G>C p.V844L | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KNOP1 | c.459_462del p.E154Kfs*58 | Frame Shift Del (DEL) | VAF 29/206 reads (14%) | called by mutect2, pindel, varscan2
- LIPC | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LYPD3 | c.382+4C>A | Splice Region (SNP) | VAF 85/513 reads (17%) | called by muse, mutect2, varscan2
- MAPK15 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- MED13 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MLLT3 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MPV17L2 | c.223T>A p.F75I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MTHFD1L | c.1056del p.K352Nfs*52 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | called by mutect2, pindel, varscan2
- MUC17 | c.10990_10994del p.T3664Cfs*15 | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | called by mutect2, pindel
- MYH7B | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- OTOA | c.2187C>G p.D729E (on ENST00000286149; = p.D715E on NM_144672.4) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PCDHB6 | c.1348A>C p.T450P | Missense Mutation (SNP) | VAF 67/592 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PDAP1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- PLEKHA4 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R16B | c.46A>T p.K16* | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- PRELP | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RALGAPA2 | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS14 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RXRA | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 78/471 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR2 | c.11177A>G p.Y3726C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SACS | c.8626G>A p.E2876K | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SDCCAG8 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC1A5 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 64/385 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A14 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- SPEM1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SPINK4 | c.216-5C>T | Splice Region (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- TEDC1 | c.574dup p.L192Pfs*19 | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | called by mutect2, pindel
- TTC3 | c.5646T>G p.S1882R | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- UTP23 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR35 | c.414del p.V139* | Frame Shift Del (DEL) | VAF 39/271 reads (14%) | called by mutect2, pindel, varscan2
- ZBTB11 | c.3050T>A p.M1017K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF750 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF91 | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ZSCAN29 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- AKAP9 | c.6738G>A p.K2246= (on ENST00000359028; = p.K2222= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs1262023240; called by muse, mutect2, varscan2
- FBN2 | c.3798C>T p.C1266= | Silent (SNP) | VAF 77/449 reads (17%) | called by muse, mutect2, varscan2
- FUT5 | c.147T>A p.L49= | Silent (SNP) | VAF 64/447 reads (14%) | called by muse, mutect2, varscan2
- FZD9 | c.1248C>T p.F416= | Silent (SNP) | VAF 32/211 reads (15%) | catalogued as COSV60669665; called by muse, mutect2, varscan2
- HDAC7 | c.351G>T p.L117= (on ENST00000427332; = p.L156= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/74 reads (15%) | called by mutect2, varscan2
- ITGB1BP1 | c.294T>C p.D98= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs201976301, COSV99432091; called by muse, mutect2, varscan2
- MANBA | c.1986A>G p.K662= (on ENST00000642252; = p.K616= on NM_005908.4) | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as CD065752; called by muse, mutect2, varscan2
- MED13 | c.2292T>C p.R764= | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- MUC6 | c.4662C>A p.T1554= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs755302968, COSV70143201; called by muse, varscan2
- SNX25 | c.1617T>C p.V539= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as rs1248221421; called by muse, mutect2
- THEM4 | c.75G>A p.P25= | Silent (SNP) | VAF 41/202 reads (20%) | called by muse, mutect2, varscan2
- AC009053.1 | chr16:74336615 C>T | 3'Flank (SNP) | VAF 20/426 reads (5%) | called by muse, mutect2
- AC009053.1 | chr16:74336616 C>A | 3'Flank (SNP) | VAF 21/431 reads (5%) | called by muse, mutect2
- AQP3 | c.-42C>A | 5'UTR (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- CC2D1B | c.*386_*391del | 3'UTR (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.*202C>T | 3'UTR (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- CEACAM21 | c.-4G>A | 5'UTR (SNP) | VAF 18/154 reads (12%) | catalogued as rs1489304664; called by muse, mutect2, varscan2
- CELP | chr9:133086294 C>G | 3'Flank (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- DCAF17 | c.*602T>C | 3'UTR (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- DLGAP4 | c.1648+15587_1648+15588del | Intron (DEL) | VAF 24/220 reads (11%) | called by mutect2, pindel, varscan2
- FAM205BP | n.923G>T | RNA (SNP) | VAF 56/449 reads (12%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662466 A>G | 5'Flank (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- GNG2 | c.87+1162del | Intron (DEL) | VAF 16/142 reads (11%) | called by mutect2, pindel*
- METTL15 | c.779-2272C>T | Intron (SNP) | VAF 12/148 reads (8%) | catalogued as rs768331835; called by muse, mutect2
